Somatic mutation profile of tumor specimen C3L-01958-01 (aliquot CPT0100370009) from CPTAC case C3L-01958, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.0 years (22,636 days).
Specimen C3L-01958-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e786ff26-2b12-47f9-a115-946e4a6d0b05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01958-31 (Blood Derived Normal), aliquot CPT0101910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8ea3072-9420-487a-83d2-95db2defedc1

The open-access MAF lists 96 somatic variants for this specimen: 68 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Nonsense Mutation 5, Frame Shift Del 5, Intron 4, 3'UTR 4, 5'UTR 3, Frame Shift Ins 3, Splice Site 2, RNA 2, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 163/457 reads (36%) | hotspot (GDC flag); catalogued as rs5030817, CS071276, CS941547, CS961706, COSV56542304, COSV56544494, COSV56544554, COSV56553901; ClinVar: pathogenic; called by muse, varscan2
- CSMD3 | c.6290T>G p.V2097G (on ENST00000297405 / NM_001363185.1; = p.V1993G on NM_052900.3) | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV52181237, COSV99844343; called by muse, mutect2, varscan2
- DCAF8L2 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 141/235 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV101445778, COSV70552533; called by muse, mutect2, varscan2
- DLL4 | c.1546C>A p.R516S | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV51062304; called by muse, mutect2, varscan2
- ITGB6 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV99324052; called by muse, mutect2, varscan2
- KCNH5 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 93/332 reads (28%) | catalogued as COSV59773889; called by muse, mutect2, varscan2
- KIF5A | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 180/788 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1422332328, COSV54055787; called by muse, mutect2, varscan2
- LRP1 | c.10121G>A p.C3374Y | Missense Mutation (SNP) | VAF 133/527 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99675794; called by muse, mutect2, varscan2
- MYO1C | c.2521C>T p.R841C (on ENST00000648651 / NM_001080779.2; = p.R806C on NM_033375.5) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs762080917, COSV100704501; called by muse, mutect2, varscan2
- NCOR1 | c.6332A>C p.H2111P | Missense Mutation (SNP) | VAF 174/543 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV51965321; called by muse, mutect2, varscan2
- PRAMEF11 | c.419G>C p.C140S | Missense Mutation (SNP) | VAF 244/985 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as rs1380495257; called by muse, mutect2, varscan2
- PTEN | c.632_633dup p.N212Afs*10 | Frame Shift Ins (INS) | VAF 74/210 reads (35%) | catalogued as CI004544; called by mutect2, pindel, varscan2
- RASSF5 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs782190148; called by muse, mutect2, varscan2
- SLC12A3 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 159/511 reads (31%) | catalogued as COSV52635064; called by muse, mutect2, varscan2
- SLC14A1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 261/879 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58934907; called by muse, mutect2, varscan2
- SMARCA4 | c.3475G>T p.G1159W | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60788830, COSV60801962; called by muse, mutect2, varscan2
- TRARG1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1567927245; called by muse, mutect2, varscan2
- ZNF106 | c.2633G>A p.S878N | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1221829711; called by muse, mutect2
- AC023055.1 | c.1467G>C p.K489N | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL3 | c.86_87del p.F29Cfs*3 | Frame Shift Del (DEL) | VAF 86/375 reads (23%) | called by mutect2, pindel, varscan2
- ANTXRL | c.588T>C p.A196= | Splice Region (SNP) | VAF 116/429 reads (27%) | called by muse, mutect2, varscan2
- ATF7IP | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- BORA | c.1190A>C p.D397A (on ENST00000613797; = p.D322A on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/364 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- C12orf43 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 240/493 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CASP4 | c.939G>C p.W313C | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCL27 | c.256T>G p.S86A | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCSER1 | c.2590G>T p.G864* | Nonsense Mutation (SNP) | VAF 97/315 reads (31%) | called by muse, mutect2, varscan2
- CFAP43 | c.3050A>G p.Y1017C | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CKB | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CLCN7 | c.2076G>T p.V692= | Splice Region (SNP) | VAF 170/617 reads (28%) | called by muse, mutect2, varscan2
- COL5A2 | c.3889G>T p.D1297Y | Missense Mutation (SNP) | VAF 197/643 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DIS3 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DYNC1H1 | c.11612T>C p.V3871A | Missense Mutation (SNP) | VAF 212/700 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- E2F2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 67/213 reads (31%) | called by muse, mutect2, varscan2
- EDF1 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ESPL1 | c.3734A>G p.K1245R | Missense Mutation (SNP) | VAF 362/845 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- HCN4 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCND2 | c.1108_1110delinsG p.T370Afs*5 | Frame Shift Del (DEL) | VAF 45/215 reads (21%) | called by pindel, varscan2*
- KDM5C | c.1816A>C p.N606H | Missense Mutation (SNP) | VAF 201/363 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- LNPEP | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRTM2 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 133/631 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED17 | c.1644_1645dup p.L549Hfs*2 | Frame Shift Ins (INS) | VAF 204/837 reads (24%) | called by pindel, varscan2
- MGAM | c.4210A>T p.N1404Y | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MIEF2 | c.525_526insAA p.F176Nfs*104 | Frame Shift Ins (INS) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- MORC3 | c.2686_2687del p.R896Sfs*2 | Frame Shift Del (DEL) | VAF 65/266 reads (24%) | called by mutect2, pindel, varscan2
- MYO5C | c.3478G>C p.D1160H | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NAGPA | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 68/211 reads (32%) | PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NCAM2 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- NLRC4 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- ODF2 | c.247del p.E83Rfs*20 (on ENST00000434106 / NM_153433.2; = p.E127Rfs*20 on NM_153432.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/192 reads (29%) | called by mutect2, pindel, varscan2
- OR8K1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1394C>A p.S465Y (on ENST00000259318 / NM_001136562.3; = p.S696Y on NM_007203.5) | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PARD3 | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PARD3 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 71/347 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PHETA2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 161/451 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- RBMXL2 | c.199A>T p.R67* | Nonsense Mutation (SNP) | VAF 175/577 reads (30%) | called by muse, mutect2, varscan2
- SSR1 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 141/487 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- STIL | c.3804del p.M1268Ifs*4 | Frame Shift Del (DEL) | VAF 74/238 reads (31%) | called by mutect2, pindel, varscan2
- STXBP2 | c.579-2A>C p.X193_splice | Splice Site (SNP) | VAF 142/515 reads (28%) | called by muse, mutect2, varscan2
- STXBP5 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SUSD6 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TTN | c.22520T>G p.I7507S (on ENST00000591111; = p.I6580S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/286 reads (33%) | PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- UBOX5 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WWP2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ZGPAT | c.1040A>G p.E347G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ZMYND8 | c.1207A>T p.M403L (on ENST00000311275 / NM_001363741.2; = p.M423L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF438 | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 177/648 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF823 | c.459_476del p.H154_T159del (on ENST00000341191 / NM_001297610.2; = p.H110_T115del on NM_017507.2) | In Frame Del (DEL) | VAF 124/514 reads (24%) | called by mutect2, pindel, varscan2
- ACOT1 | c.57G>A p.V19= | Silent (SNP) | VAF 128/411 reads (31%) | called by muse, mutect2, varscan2
- B4GALT2 | c.45T>C p.A15= | Silent (SNP) | VAF 85/286 reads (30%) | called by muse, mutect2, varscan2
- CPD | c.3180C>T p.G1060= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as COSV56712269; called by muse, mutect2, varscan2
- DOP1B | c.6408C>G p.P2136= | Silent (SNP) | VAF 100/352 reads (28%) | called by muse, mutect2, varscan2
- FAM3C | c.453T>C p.D151= | Silent (SNP) | VAF 69/262 reads (26%) | called by muse, mutect2, varscan2
- FPR2 | c.693G>A p.K231= | Silent (SNP) | VAF 168/558 reads (30%) | catalogued as COSV60672061; called by muse, mutect2, varscan2
- HMGCL | c.117T>C p.G39= | Silent (SNP) | VAF 184/661 reads (28%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.78C>T p.H26= | Silent (SNP) | VAF 69/346 reads (20%) | catalogued as rs751374608; called by muse, mutect2, varscan2
- KMT2D | c.11088A>G p.S3696= | Silent (SNP) | VAF 62/324 reads (19%) | catalogued as rs1459341788; called by muse, mutect2, varscan2
- LRRC45 | c.936G>C p.L312= | Silent (SNP) | VAF 50/181 reads (28%) | called by muse, mutect2, varscan2
- MAGEB3 | c.654C>A p.A218= | Silent (SNP) | VAF 139/248 reads (56%) | called by muse, mutect2, varscan2
- SCN1A | c.924T>A p.T308= | Silent (SNP) | VAF 64/197 reads (32%) | called by muse, mutect2, varscan2
- SEC62 | c.276C>T p.H92= | Silent (SNP) | VAF 134/434 reads (31%) | called by mutect2, varscan2
- TMPRSS7 | c.145C>A p.R49= | Silent (SNP) | VAF 135/344 reads (39%) | called by muse, mutect2, varscan2
- VWA3A | c.2799G>T p.V933= | Silent (SNP) | VAF 83/266 reads (31%) | called by muse, mutect2, varscan2
- AC011330.1 | n.1014del | RNA (DEL) | VAF 58/168 reads (35%) | called by mutect2, varscan2
- CCHCR1 | c.-8A>C | 5'UTR (SNP) | VAF 163/587 reads (28%) | called by muse, mutect2, varscan2
- COG6 | c.*394del | 3'UTR (DEL) | VAF 91/284 reads (32%) | called by mutect2, pindel, varscan2
- FUS | c.190+126C>T | Intron (SNP) | VAF 52/177 reads (29%) | called by muse, mutect2, varscan2
- GLO1 | c.*48G>T | 3'UTR (SNP) | VAF 69/241 reads (29%) | called by muse, mutect2, varscan2
- LAMB2 | c.4224+28G>A | Intron (SNP) | VAF 215/488 reads (44%) | called by muse, mutect2, varscan2
- PTENP1 | n.1740C>T | RNA (SNP) | VAF 216/800 reads (27%) | catalogued as rs1381559311; called by muse, mutect2, varscan2
- RBP3 | c.-10C>A | 5'UTR (SNP) | VAF 113/398 reads (28%) | called by muse, mutect2, varscan2
- RBP3 | c.-9T>A | 5'UTR (SNP) | VAF 111/397 reads (28%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.*18G>T | 3'UTR (SNP) | VAF 60/230 reads (26%) | called by muse, mutect2, varscan2
- TBX5 | c.*32_*50del | 3'UTR (DEL) | VAF 92/632 reads (15%) | called by mutect2, pindel, varscan2
- TSN | c.67-648T>A | Intron (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- ZGRF1 | c.102+3279A>T | Intron (SNP) | VAF 64/264 reads (24%) | called by muse, mutect2, varscan2
